Somatic mutation profile of tumor specimen 0DVJOL from CCDI case PBCMXN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,722 days).
Specimen 0DVJOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30b9125b-4fb5-42b2-be07-9e9eebc8a500.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bbedd0f-57b7-4c80-a9ce-9d46d6dea488

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/638 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NCAM1 | c.1126C>T p.R376C (on ENST00000316851 / NM_181351.5; = p.R366C on NM_000615.7) | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs974871438, COSV57528190; called by muse, mutect2
- TTN | c.58798T>A p.S19600T (on ENST00000591111; = p.S12176T on NM_003319.4) | Missense Mutation (SNP) | VAF 28/867 reads (3%) | PolyPhen probably damaging (0.991); called by muse, mutect2
